Somatic mutation profile of tumor specimen 0D8Y4Q from CCDI case PBBHUB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pineoblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.1 years (411 days).
Specimen 0D8Y4Q: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3478d375-e5d7-4caa-839a-a67b479659ca.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0D8Y4P (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5e15fcdc-9784-4a7c-9413-93d66a6180e2

The open-access MAF lists 8 somatic variants for this specimen: 3 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 4, Missense Mutation 3, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SLC9B1 | c.991G>A p.V331I | Missense Mutation (SNP) | VAF 220/589 reads (37%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.844); catalogued as rs182377523; called by muse, mutect2, varscan2
- TEDC1 | c.1294C>T p.R432W (on ENST00000392523 / NM_001367178.1; = p.R363W on NM_001134875.1) | Missense Mutation (SNP) | VAF 11/208 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs369370157; called by muse, mutect2
- EXOC5 | c.676T>G p.S226A | Missense Mutation (SNP) | VAF 14/326 reads (4%) | SIFT tolerated (0.28); PolyPhen benign (0.007); called by muse, mutect2
- ANKRD28 | c.1042C>A p.R348= | Silent (SNP) | VAF 256/668 reads (38%) | called by muse, mutect2, varscan2
- CEP85L | c.1407T>C p.F469= | Silent (SNP) | VAF 28/666 reads (4%) | called by muse, mutect2
- ERLIN2 | c.390G>T p.V130= | Silent (SNP) | VAF 26/775 reads (3%) | called by muse, mutect2
- SLC7A9 | c.588G>C p.L196= | Silent (SNP) | VAF 144/330 reads (44%) | called by muse, varscan2
- SP100 | c.1429+14G>T | Intron (SNP) | VAF 131/383 reads (34%) | called by muse, mutect2, varscan2
